Somatic mutation profile of tumor specimen MP2PRT-PASUMM-TMP1-A (aliquot MP2PRT-PASUMM-TMP1-A-1-0-D-A81O-36) from MP2PRT case MP2PRT-PASUMM, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.8 years (649 days).
Specimen MP2PRT-PASUMM-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cbc9e6bd-d97f-458f-ad1a-0e025b620a36.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASUMM-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASUMM-NB1-A-1-0-D-A81O-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c311ba4c-b8ff-4a62-bd3e-648df95d0d99

The open-access MAF lists 13 somatic variants for this specimen: 12 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 12, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 17/45 reads (38%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.844); catalogued as rs121913527, COSV55501778, COSV55541748, COSV55727828; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- MTOR | c.6644C>T p.S2215F | Missense Mutation (SNP) | VAF 171/405 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as rs587777894, COSV63868278, COSV63868313; ClinVar: not provided / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CACNA1E | c.2755C>T p.R919W | Missense Mutation (SNP) | VAF 141/323 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs769941881, COSV62394979, COSV62397581; called by muse, mutect2, varscan2
- DNAJC6 | c.284G>A p.R95Q | Missense Mutation (SNP) | VAF 137/309 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.679); catalogued as rs759567966, COSV54768935; called by muse, mutect2, varscan2
- DZANK1 | c.1504C>T p.R502W (on ENST00000262547 / NM_001099407.1; = p.R309W on NM_018152.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 148/322 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755349093, COSV52755285; called by muse, mutect2, varscan2
- FAM47B | c.215G>A p.R72H | Missense Mutation (SNP) | VAF 269/288 reads (93%) | SIFT tolerated (0.24); PolyPhen benign (0.071); catalogued as rs773446343, COSV61452777; called by muse, mutect2, varscan2
- PON3 | c.693G>T p.Q231H | Missense Mutation (SNP) | VAF 106/220 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.435); catalogued as COSV55700483; called by muse, mutect2, varscan2
- POTEC | c.410G>A p.R137Q | Missense Mutation (SNP) | VAF 318/679 reads (47%) | SIFT tolerated (0.52); PolyPhen benign (0.005); catalogued as rs568578586, COSV100744071; called by muse, mutect2, varscan2
- SLC6A7 | c.779G>A p.R260H | Missense Mutation (SNP) | VAF 217/780 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs371610896; called by muse, mutect2, varscan2
- C2orf81 | c.979G>A p.G327R | Missense Mutation (SNP) | VAF 339/814 reads (42%) | SIFT tolerated (0.64); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- IGHV1-69 | chr14:106714682 TCT>GGGGG | Missense Mutation (INS) | VAF 74/155 reads (48%) | called by pindel, varscan2*
- ZRANB2 | c.119C>T p.T40I | Missense Mutation (SNP) | VAF 98/234 reads (42%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- MED13L | c.2670G>A p.E890= | Silent (SNP) | VAF 183/401 reads (46%) | called by muse, mutect2, varscan2
